Somatic mutation profile of tumor specimen 0DQ18H from CCDI case PBCEGU, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 10.9 years (3,995 days).
Specimen 0DQ18H: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a2931887-4ad1-40be-aae0-67544fb9d043.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQ18M (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/af4f7a71-4c1c-42f6-91d8-3bb4ff1e5395

The open-access MAF lists 40 somatic variants for this specimen: 26 protein-altering or splice-affecting, 9 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 9, 3'UTR 3, Intron 2, Frame Shift Del 1, Nonsense Mutation 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 105/373 reads (28%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1057519903, COSV64731746, COSV64731769; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.380C>T p.S127F | Missense Mutation (SNP) | VAF 235/314 reads (75%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730881999, COSV52666031, COSV52675881, COSV52731113, COSV52828604; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ARHGEF10 | c.1873A>G p.I625V (on ENST00000398564; = p.I600V on NM_014629.4) | Missense Mutation (SNP) | VAF 28/560 reads (5%) | SIFT tolerated (0.93); PolyPhen benign (0.003); catalogued as rs1345340119; called by muse, mutect2
- ATRX | c.655C>A p.Q219K | Missense Mutation (SNP) | VAF 89/468 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as COSV64882344; called by muse, mutect2, varscan2
- BANP | c.1261G>A p.V421M (on ENST00000286122; = p.V393M on NM_017869.4) | Missense Mutation (SNP) | VAF 133/387 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.991); catalogued as rs138252049; called by muse, mutect2, varscan2
- LIM2 | c.130C>T p.R44W | Missense Mutation (SNP) | VAF 55/126 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs374509682; called by muse, mutect2, varscan2
- LMBR1 | c.1268A>G p.N423S | Missense Mutation (SNP) | VAF 78/589 reads (13%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.989); catalogued as rs750834412; called by muse, mutect2, varscan2
- LRRTM3 | c.550G>T p.E184* | Nonsense Mutation (SNP) | VAF 66/365 reads (18%) | catalogued as COSV63671949; called by muse, mutect2, varscan2
- OR14K1 | c.916G>A p.V306I | Missense Mutation (SNP) | VAF 105/598 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV51722651; called by muse, mutect2, varscan2
- OR52J3 | c.308T>A p.M103K | Missense Mutation (SNP) | VAF 14/292 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as COSV66747985; called by muse, mutect2
- PDGFRA | c.1154A>T p.K385M | Missense Mutation (SNP) | VAF 696/1120 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV57264818; called by muse, mutect2, varscan2
- PTPRCAP | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 11/128 reads (9%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.222); catalogued as COSV100396820; called by muse, mutect2
- TRPM3 | c.3856C>T p.R1286C (on ENST00000357533 / NM_001366142.2; = p.R1141C on NM_020952.6) | Missense Mutation (SNP) | VAF 41/139 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as rs148061413, COSV62597388; called by muse, mutect2, varscan2
- CD46 | c.1164A>T p.K388N | Missense Mutation (SNP) | VAF 29/962 reads (3%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.007); called by muse, mutect2
- CRYBA2 | c.271C>G p.Q91E | Missense Mutation (SNP) | VAF 54/158 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.166); called by muse, varscan2
- FOXA1 | c.1307G>T p.S436I | Missense Mutation (SNP) | VAF 51/150 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.597); called by muse, mutect2, varscan2
- HMCN2 | c.10582del p.Q3528Rfs*17 | Frame Shift Del (DEL) | VAF 31/116 reads (27%) | called by mutect2, varscan2
- MCM9 | c.3361T>C p.F1121L | Missense Mutation (SNP) | VAF 76/584 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NDST3 | c.825C>A p.N275K | Missense Mutation (SNP) | VAF 193/619 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- NLRC4 | c.1255G>A p.D419N | Missense Mutation (SNP) | VAF 125/232 reads (54%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.57); called by muse, mutect2, varscan2
- OR4F4 | c.640A>T p.I214F | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- OR9A2 | c.110C>A p.T37K | Missense Mutation (SNP) | VAF 54/350 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); called by muse, varscan2
- RXRG | c.196C>A p.L66M | Missense Mutation (SNP) | VAF 18/143 reads (13%) | SIFT tolerated, low confidence (0.48); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- SHCBP1L | c.1648C>A p.H550N | Missense Mutation (SNP) | VAF 87/692 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- SI | c.1812C>A p.D604E | Missense Mutation (SNP) | VAF 232/709 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZMYM2 | c.2176A>T p.T726S | Missense Mutation (SNP) | VAF 149/569 reads (26%) | SIFT tolerated (0.49); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- ADGRG3 | c.756C>T p.F252= | Silent (SNP) | VAF 18/136 reads (13%) | catalogued as rs548387435, COSV59652213; called by mutect2, varscan2
- GDF2 | c.496C>T p.L166= | Silent (SNP) | VAF 64/286 reads (22%) | called by muse, mutect2, varscan2
- OR9A2 | c.111A>T p.T37= | Silent (SNP) | VAF 59/377 reads (16%) | called by muse, mutect2, varscan2
- PCDH15 | c.2352C>T p.Y784= | Silent (SNP) | VAF 89/414 reads (21%) | called by muse, mutect2, varscan2
- PDGFRA | c.1155G>A p.K385= | Silent (SNP) | VAF 696/1124 reads (62%) | called by muse, mutect2, varscan2
- PMP22 | c.252C>T p.F84= | Silent (SNP) | VAF 70/708 reads (10%) | called by muse, mutect2
- PRDM12 | c.984C>T p.T328= | Silent (SNP) | VAF 3/26 reads (12%) | called by muse, varscan2
- SLC25A53 | c.171C>T p.I57= | Silent (SNP) | VAF 25/102 reads (25%) | called by muse, mutect2, varscan2
- XRN2 | c.849G>A p.K283= | Silent (SNP) | VAF 109/536 reads (20%) | called by muse, mutect2, varscan2
- CAVIN3 | c.384+71G>T | Intron (SNP) | VAF 7/19 reads (37%) | called by muse, mutect2
- DNAJC24 | c.*2189G>A | 3'UTR (SNP) | VAF 59/420 reads (14%) | called by muse, mutect2, varscan2
- IMMP1L | c.322-12C>T | Intron (SNP) | VAF 105/493 reads (21%) | called by muse, mutect2, varscan2
- KIR2DL1 | c.*11C>A | 3'UTR (SNP) | VAF 16/136 reads (12%) | called by muse, mutect2, varscan2
- SLC7A13 | c.*28T>C | 3'UTR (SNP) | VAF 67/514 reads (13%) | catalogued as rs748651441; called by muse, mutect2, varscan2
